Surgical pathology report (de-identified scan), TCGA case TCGA-NK-A5CR, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Rush University, specimen TCGA-NK-A5CR-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3
Carcinoma, squamous cell
Site (R) Lung, upper lobe
8070/3
C34.1
JW 1/14/13

PATHOLOGY SURGICAL

Results

Status: Final result

Entry Date

Component Results

PATHOLOGY RESULT:

Department of Pathology

Final

Clinical Data Repository* This report may not match the original report format

FINAL DIAGNOSIS

A. (Lung, right upper lobe; wedge resection): Squamous cell carcinoma, grade 2, extending to the visceral pleura and measuring 1.9 cm in greatest dimension.

No convincing lymphatic permeation seen.

Margins of resection free of tumor.

Stage pT2N0Mx

Remaining lung without pathologic changes.

B. (Level 7 lymph node; biopsy): Fragments of lymph nodes negative for metastatic tumor.

C. (Level 4 lymph node; biopsy): Fragments of lymph nodes negative for metastatic tumor.

D. (Lung, right upper lobe; wedge resection): Segment of benign lung tissue with subpleural and interstitial fibrosis and chronic inflammation.

[page 2 of 4]
INTRAOPERATIVE CONSULTATION

A. FROZEN:WEDGE RESECTION RIGHT UPPER LOBE, DISTANT FROM STAPLE LINE: Suture line is negative for tumor. Grossly, tumor 0.6cm-0.7 cm from stapled margin. (A91, A92)

GROSS DESCRIPTION

A. The specimen is labeled frozen, wedge resection right upper lobe. Received fresh is a 22.0 gram, 8.0 x 3.5 x 1.9 cm wedge of lung with a 9.5 cm staple margin. The pleura is inked blue and the staple margin is submitted for frozen section with the remnant placed in cassettes A91 and A92. After the staple margin is removed, the underlying lung parenchyma is inked orange. There is a 1.9 x 1.7 x 1.5 cm firm white and black nodule causing pleural puckering and located approximately 0.6 to 0.7 cm from the staple margin. Sections are submitted as follows: A91 and A92- staple margin; A1 - tumor closest to staple margin, A2 and A3 - tumor closest to pleura; A4 remainder of tumor; A5 - normal lung away from tumor.

B. The specimen is labeled level 7 lymph node. Received in formalin are multiple fragments of soft tan tissue measuring in aggregate 1.2 x 0.8 x 0.4 cm. The fragments are wrapped and submitted entirely in cassette B1.

C. The specimen is labeled level 4 lymph node. Received in formalin are multiple small fragments of soft red and black tissue measuring in aggregate 1.3 x 0.5 x 0.5 cm. The specimen is entirely wrapped and submitted in cassette C1.

D. The specimen is labeled wedge resection, right upper. Received fresh is a 22 gram, 13 x 2.5 x 1.5 cm segment of lung with a 13 cm and 14 cm staple margin, which are variably located from 1.1 to 2.1 cm apart. The lung parenchyma is soft, red and unremarkable. No tumor masses are seen. The pleura is inked blue and the 13 cm margin is submitted in cassettes D1 and D2, the 14 cm margin is submitted in cassettes D3 and D4 and two representative sections of the lung are submitted in cassettes D5 and D6.

SPECIMEN(S) RECEIVED

A: FROZEN:WEDGE RESECTION RIGHT UPPER LOBE, DISTANT FROM STAPLE LINE

B: LEVEL 7 LYMPH NODE

C: LEVEL 4 LYMPH NODE

D: WEDGE RESECTION RIGHT UPPER LOBE #2

* The above listed tests (if any) were developed and the performance characteristics determined by Department of Pathology. These tests have not been cleared or approved for commercial use by the U.S. Food and Drug Administration. The FDA has determined that FDA review is not required for such in-house assays. (21 CFR 809.30(e))

OPERATIVE INFORMATION

[page 3 of 4]
Diagnosis: RUL NSCLC

Procedure: Bronchoscopy flexible fiberoptic, thoracoscopy video assisted

INTRADEPARTMENT CONSULTATION PATHOLOGIST: QA COMMITTEE

ICD-9(s): 162.3

CPT(s): A: 88309, 88331, 88332

B: 88305

C: 88305

D: 88309

The attending pathologist was physically present when this specimen was diagnosed, and actively participated in all key decisions.

Lab and Collection

PATHOLOGY SURGICAL

Pathology

[page 4 of 4]
Procedure Location:

HIIPAA Discrepancy	☒	☒

Source: NCI Genomic Data Commons file d7c728ee-d25b-462a-a024-9a3ae26f47de (TCGA-NK-A5CR.487D0915-7A8B-4092-98F8-A0E7A757E79C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).